Somatic mutation profile of tumor specimen ALCH-ADWT-TTP1-A (aliquot ALCH-ADWT-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-ADWT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.0 years (19,348 days).
Specimen ALCH-ADWT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65133025-a748-4003-9dde-cd389b26eb2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADWT-NB1-A (Blood Derived Normal), aliquot ALCH-ADWT-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4698221c-a27e-4e16-84ed-c8a627f7cb8c

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Nonsense Mutation 3, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM10 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 75/364 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as rs918702048; called by muse, mutect2, varscan2
- CACNG3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV50065936, COSV50070650; called by muse, mutect2, varscan2
- CHST9 | c.204G>C p.M68I | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs761305003; called by muse, varscan2
- CREB3L2 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.444); catalogued as rs1165903688; called by muse, mutect2, varscan2
- FOXN4 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 88/435 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs144504080; called by muse, mutect2, varscan2
- FRK | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.251); catalogued as COSV73384001; called by muse, mutect2, varscan2
- GRIN3B | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762752908; called by muse, mutect2, varscan2
- KAT7 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 103/531 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs200590185; called by muse, mutect2, varscan2
- OR10G2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 68/786 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1369449667; called by muse, mutect2
- OR8D2 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199640883; called by muse, mutect2, varscan2
- PTPRO | c.1838G>A p.W613* | Nonsense Mutation (SNP) | VAF 114/548 reads (21%) | catalogued as rs1470559975; called by muse, mutect2, varscan2
- TMEM169 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143173919; called by muse, mutect2, varscan2
- TTC27 | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs889756340, COSV58649033; called by muse, mutect2, varscan2
- ZKSCAN4 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV66023351; called by muse, mutect2, varscan2
- ZNF616 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs759966710; called by muse, mutect2
- AGPAT5 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CCDC110 | c.1012A>T p.R338* | Nonsense Mutation (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- COL9A3 | c.255T>C p.D85= | Splice Region (SNP) | VAF 59/372 reads (16%) | called by muse, mutect2, varscan2
- DNER | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD3 | c.1788C>A p.D596E | Missense Mutation (SNP) | VAF 156/404 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HTR3A | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 120/511 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIAA2013 | c.1535A>G p.E512G | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MTR | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 151/851 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MXD1 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 47/268 reads (18%) | called by muse, mutect2, varscan2
- PDS5B | c.3956C>T p.S1319F | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); called by muse, varscan2
- PLCXD1 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- RIOX1 | c.649C>G p.H217D | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMIM20 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- STUB1 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SULT4A1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TEKT2 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 228/1599 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZBTB7C | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.175); called by muse, mutect2
- ABTB2 | c.2928C>G p.L976= | Silent (SNP) | VAF 71/522 reads (14%) | catalogued as rs753941809; called by muse, mutect2, varscan2
- CALB2 | c.441C>T p.Y147= | Silent (SNP) | VAF 115/354 reads (32%) | catalogued as rs1193560098; called by muse, varscan2
- DMBT1 | c.3516A>T p.P1172= (on ENST00000338354 / NM_001377530.1; = p.P673= on NM_004406.3) | Silent (SNP) | VAF 59/1028 reads (6%) | called by muse, mutect2
- EME2 | c.430C>T p.L144= | Silent (SNP) | VAF 113/456 reads (25%) | catalogued as COSV99167610; called by muse, mutect2, varscan2
- FMN2 | c.117C>T p.S39= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1004240278; called by muse, mutect2, varscan2
- OR10H5 | c.360C>T p.Y120= | Silent (SNP) | VAF 48/201 reads (24%) | catalogued as rs772836837, COSV58277328; called by muse, mutect2, varscan2
- OR4A15 | c.21G>A p.V7= | Silent (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- RAB6C | c.714T>C p.P238= | Silent (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2
- RABGGTB | c.30C>T p.I10= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs11548708; called by muse, mutect2, varscan2
- TSPY1 | c.300T>C p.P100= | Silent (SNP) | VAF 98/568 reads (17%) | called by mutect2, varscan2
- XKR4 | c.1551A>T p.G517= | Silent (SNP) | VAF 71/347 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.4090T>A | RNA (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- EXOSC9 | c.1157-214C>A | Intron (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
